Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MH-01A (Primary Tumor).

1CD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

Site: Endometrium C54.1 for 5/3/11

FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY -

- A. OVARY WITH MATURE CYSTIC TERATOMA, NO ADENOCARCINOMA IS SEEN.
- B. FALLOPIAN TUBE, STATUS POST TUBAL LIGATION, NO TUMOR SEEN.

PART 2: UTERUS, LEFT OVARY AND FALLOPIAN TUBE, TOTAL ABDOMINAL HYSTERECTOMY, LEFT SALPINGO-OOPHORECTOMY AND FROZEN SECTION (220 GRAMS) -

- A. ENDOMETRIUM WITH MODERATELY DIFFERENTIATED ENDOMETRIOID ADENOCARCINOMA (GRADE 2) WITH SQUAMOUS DIFFERENTIATION, INVOLVING ABOUT 90% OF THE ENDOMETRIAL SURFACE AND PENETRATING UP TO 80% OF MYOMETRIAL THICKNESS (2I and 2J) (see comment).
- B. UNINVOLVED ENDOMETRIUM WITH ATYPICAL COMPLEX HYPERPLASIA.
- C. ADENOMYOSIS.
- D. CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA AND PARAKERATOSIS.
- E. UTERINE CERVIX WITH TUBAL METAPLASIA (ENDOSALPINGIOSIS) AND ENDOMETRIOSIS.
- F. UTERINE SEROSAL ADHESIONS.
- G. LEFT OVARY WITH MICROSCOPIC MATURE CYSTIC TERATOMA AND SEROSAL ADHESIONS, NO ADENOCARCINOMA IS SEEN.
- H. LEFT FALLOPIAN TUBE, STATUS POST TUBAL LIGATION, NO TUMOR SEEN.

PART 3: LYMPH NODES, LEFT PELVIC, BIOPSY -

FOUR LYMPH NODES, FREE OF TUMOR (0/4).

PART 4: LYMPH NODES, LEFT PERIAORTIC, BIOPSY -

ONE LYMPH NODE, FREE OF TUMOR (0/1).

PART 5: LYMPH NODES, RIGHT PELVIC, BIOPSY -

ONE LYMPH NODE, FREE OF TUMOR (0/1).

PART 6: LYMPH NODES, RIGHT PERIAORTIC, BIOPSY -

TWO LYMPH NODES, FREE OF TUMOR (0/2).

COMMENT:

This endometrial adenocarcinoma represents a FIGO stage 1C, G2. The peritoneal cytology is negative.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE:

Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE:

Moderately differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 4.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90 %, Posterior endomyometrium: 90 %
Greater than 1/2 thickness of myometrium

DEPTH OF INVASION**:

No

ANGIOLYMPHATIC INVASION:

Complex endometrial hyperplasia with atypia

PRE-NEOPLASTIC CONDITIONS:

(epithelial, smooth muscle, others), Adenomyosis

OTHER:

Number of lymph nodes positive: 0

LYMPH NODES POSITIVE:

Total number of lymph nodes examined: 8

LYMPH NODES EXAMINED:

pT1c

T STAGE, PATHOLOGIC:

pN0

N STAGE, PATHOLOGIC:

pMX

M STAGE, PATHOLOGIC:

IC

FIGO STAGE:

Source: NCI Genomic Data Commons file e432669c-f414-4c61-838a-0024a46c11b1 (TCGA-BG-A0MH.F641C526-7A0D-46C3-92EE-CD9CB0D13960.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).